Somatic mutation profile of tumor specimen TCGA-D6-6824-01A (aliquot TCGA-D6-6824-01A-11D-1912-08) from TCGA case TCGA-D6-6824, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 62.0 years (22,633 days).
Specimen TCGA-D6-6824-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ee161ce5-a1ac-4ec7-b40c-7b583362a6f3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D6-6824-10A (Blood Derived Normal), aliquot TCGA-D6-6824-10A-01D-1912-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/430bdc3f-57bd-46d7-8e2e-498dfd318075

The open-access MAF lists 32 somatic variants for this specimen: 24 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 7, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.2702G>T p.C901F | Missense Mutation (SNP) | VAF 18/208 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55881149; called by muse, mutect2
- CASKIN2 | c.1706C>A p.A569E | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.447); catalogued as COSV100050669; called by muse, mutect2
- CERS3 | c.579A>T p.L193F | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); catalogued as COSV99432406; called by muse, mutect2
- DENND2D | c.222A>G p.I74M | Missense Mutation (SNP) | VAF 11/186 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.329); catalogued as COSV100718760; called by muse, mutect2
- DNAH14 | c.994A>G p.K332E (on ENST00000445597; = p.K205E on NM_144989.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.019); catalogued as COSV100835941; called by muse, mutect2
- EXTL1 | c.331C>G p.H111D | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.374); catalogued as COSV100959117; called by muse, mutect2
- FAP | c.1826A>C p.E609A | Missense Mutation (SNP) | VAF 4/95 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as COSV99502352; called by muse, mutect2
- FCN1 | c.974C>A p.P325H | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100878938; called by muse, mutect2
- GBP4 | c.1059G>C p.M353I | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as COSV100864429, COSV100864459; called by muse, mutect2
- HUWE1 | c.11074A>C p.I3692L | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.456); catalogued as COSV99473295; called by muse, mutect2
- MYH6 | c.2614C>A p.R872S | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); catalogued as COSV100676811; called by muse, mutect2
- NID2 | c.1684G>A p.D562N | Missense Mutation (SNP) | VAF 17/230 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99356937; called by muse, mutect2
- NPTX2 | c.679G>C p.V227L | Missense Mutation (SNP) | VAF 20/265 reads (8%) | SIFT tolerated (0.95); PolyPhen benign (0.017); catalogued as COSV99675013; called by muse, mutect2
- OR2L8 | c.440C>T p.S147F | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100594265, COSV100594315; called by muse, mutect2
- PCDHGA4 | c.161T>C p.L54P | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.91); catalogued as rs1220668152, COSV99542631; called by muse, mutect2
- PLEKHM1 | c.2745G>T p.M915I | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.238); catalogued as COSV101378815; called by muse, mutect2
- PLPPR1 | c.697C>A p.L233I | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as COSV100883416; called by muse, mutect2, varscan2
- PRAMEF19 | c.730G>T p.G244C | Missense Mutation (SNP) | VAF 11/256 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV65819086; called by muse, mutect2
- RUFY2 | c.1141A>G p.T381A | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT tolerated (0.52); PolyPhen benign (0.015); catalogued as rs1468530801, COSV56258633; called by muse, mutect2
- SEMA3C | c.53G>A p.C18Y | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99543423; called by muse, mutect2
- SENP5 | c.137G>A p.R46K | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.024); catalogued as COSV100052139; called by muse, mutect2
- SLC47A1 | c.1131G>T p.Q377H | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.081); catalogued as COSV99565509; called by muse, mutect2
- THSD7B | c.1558G>A p.E520K | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV99754968; called by muse, mutect2
- TRIM58 | c.500A>G p.K167R | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.334); catalogued as COSV100825179, COSV100825204; called by muse, mutect2
- CHAMP1 | c.852A>T p.S284= | Silent (SNP) | VAF 6/86 reads (7%) | catalogued as COSV100778841; called by muse, mutect2
- FREM2 | c.5967C>T p.I1989= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as COSV54846511; called by muse, mutect2
- GRIN3A | c.1191A>C p.A397= | Silent (SNP) | VAF 14/82 reads (17%) | catalogued as COSV100701670; called by muse, mutect2, varscan2
- IGHV3-16 | c.33T>A p.A11= | Silent (SNP) | VAF 8/140 reads (6%) | called by muse, mutect2
- MAGEC1 | c.1455C>T p.S485= | Silent (SNP) | VAF 7/149 reads (5%) | catalogued as COSV99594757, COSV99596093; called by muse, mutect2
- SSH2 | c.4005G>A p.Q1335= | Silent (SNP) | VAF 4/67 reads (6%) | catalogued as COSV99282580; called by muse, mutect2
- ZMAT1 | c.1602T>C p.H534= | Silent (SNP) | VAF 5/59 reads (8%) | catalogued as COSV100858876; called by muse, mutect2
- DCHS2 | n.786C>G | RNA (SNP) | VAF 12/163 reads (7%) | catalogued as COSV100252528; called by muse, mutect2
